Somatic mutation profile of tumor specimen TCGA-FR-A2OS-01A (aliquot TCGA-FR-A2OS-01A-11D-A21A-08) from TCGA case TCGA-FR-A2OS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 49.6 years (18,122 days).
Specimen TCGA-FR-A2OS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35e07225-76c9-4707-a396-b808a6cda92b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A2OS-10B (Blood Derived Normal), aliquot TCGA-FR-A2OS-10B-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c3f81eb-f686-42c4-b586-e63d05ebe21f

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD22 | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV50056285; called by muse, mutect2, varscan2
- DAPP1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV56451894; called by muse, mutect2, varscan2
- DSCAM | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV68029597; called by muse, mutect2, varscan2
- FBLN1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs774669995, COSV53049279; called by muse, mutect2, varscan2
- KIAA1210 | c.3272C>G p.T1091S | Missense Mutation (SNP) | VAF 138/329 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68177934; called by muse, mutect2, varscan2
- NPHP1 | c.1430G>A p.R477H (on ENST00000393272 / NM_207181.4; = p.R478H on NM_000272.5) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV57209622; called by muse, varscan2
- PCDHGB4 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1458700152, COSV53918954; called by muse, mutect2, varscan2
- SALL3 | c.3199G>A p.G1067S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs540892624, COSV73305995, COSV73306171; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SEPTIN6 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59715138; called by muse, mutect2, varscan2
- ZFPM2 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 125/149 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV65874388; called by muse, mutect2, varscan2
- ZNF827 | c.3145T>G p.C1049G | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65228707; called by muse, mutect2, varscan2
- ARFGAP3 | c.1317T>G p.A439= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as COSV54312607; called by muse, mutect2, varscan2
- VASN | c.432C>T p.F144= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs765216259, COSV52031407; called by muse, mutect2, varscan2
